Surgical pathology report (de-identified scan), TCGA case TCGA-2Y-A9H7, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Y-A9H7-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Final Diagnosis

A, LIVER, LEFT LOBE, RESECTION:
Hepatocellular carcinoma.
Tumor (2.5 cm) confined to liver.
Non-involved liver with fibrous expansion of portal areas and marked portal-portal and portal-central bridging fibrosis, compatible with ISHAK stage 4 of 6.
No excess iron staining.
See Key pathological Findings.

I, the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically Signed Out by

Ancillary Studies

Immunohistochemistry stains, performed with adequate controls on block A3, revealed the tumor cells to be positive for Hep-par1 and negative for CK7, CK20, CK19 and Chromogranin.
Special stains Trichrome, Iron and reticulin were performed with adequate controls on block A7 and were reviewed.

Key Pathological Findings

A: Liver, Resection
Specimen:
Liver
PROCEDURE:
Partial hepatectomy
TUMOR SIZE:
Greatest dimension: 2.5 cm
*Additional dimensions: 2.5 X 2.2 cm
TUMOR FOCALITY:
Solitary (specify location): left lobe
HISTOLOGIC TYPE:
Hepatocellular carcinoma
HISTOLOGIC GRADE:
GII: Moderately differentiated
TUMOR EXTENSION (select all that apply):
Tumor confined to liver
PRIMARY TUMOR (pT):
pT1: Solitary tumor with no vascular invasion
REGIONAL LYMPH NODES (pN):

ICD O.3
Carcinoma, hepatocellular NOS
817013
Site: Liver C22.0
JAJ 4/28/14

[page 2 of 2]
pNX: Cannot be assessed

DISTANT METASTASIS (pM):

pMX: Cannot be assessed

MARGINS:

Parenchymal margin uninvolved by invasive carcinoma

Distance of invasive carcinoma from closest margin: 12 mm

Specify margin: parenchymal resection margin

*VENOUS (LARGE VESSEL) INVASION (V):

*Absent

*ADDITIONAL PATHOLOGIC FINDINGS:

*Cirrhosis/fibrosis

Specimen(s) Received

A LEFT LOBE LIVER FS

Clinical History

Back pain, workup CT showed liver mass.

Preoperative Diagnosis

Hepatocellular carcinoma.

Intraoperative Consultation

FSA1. LEFT LOBE LIVER:

Inked margin, free of tumor.

Comment: This frozen section diagnosis/result was communicated to and acknowledged by
in at

I, have performed the intraoperative consultation and issued the above diagnosis.

Gross Description

A. The specimen is received fresh, labeled "left lobe of liver" and consists of a 73.8 gram, 14.5 x 7.0 x 2.5 cm wedge of liver. The surgical margin is inked blue. There is a 2.5 x 2.5 x 2.2 cm well circumscribed soft yellow, lobulated, centrally hemorrhagic mass. The mass is 1.2 cm from the closest surgical margin. The mass is 0.1 cm from the capsule. No additional lesions are identified. The remaining parenchyma is smooth and brown. No nodularity is identified. A representative section of the mass is frozen and entirely submitted in FSA1. Additional representative sections are submitted as follows:

A2-A3: Composite section of mass with margin and adjacent normal parenchyma
A4-A5: Additional composite section of mass with margin and normal Parenchyma
A6: Mass
A7: Normal parenchyma.

A portion of tissue is submitted to Tissue Procurement Laboratory.

Source: NCI Genomic Data Commons file a77eea7b-757a-4f40-84c3-9f07070d74c2 (TCGA-2Y-A9H7.80E07DD4-2925-4F58-B4DA-07041673A13F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).